Gene-level copy-number profile of tumor specimen TCGA-D5-6923-01A from TCGA case TCGA-D5-6923, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 57.8 years (21,118 days).
Specimen TCGA-D5-6923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d896fbc8-6813-49d3-8615-59778d3713a6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6923-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48414e09-65c0-4846-ad4c-ca7e1d850dfb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,520; copy number 3: 3,527; copy number 4: 39,180; copy number 5: 6,433; copy number 6: 2,219; copy number 7: 1,283; copy number 8: 87; copy number 9: 253; copy number 10: 188; copy number 11: 2,125.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6923-01A-11D-1923-01): tumor purity 0.64, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,566 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:32,911,493–35,796,550, 37 genes, copy number 10: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr8:36,308,245–37,674,387, 22 genes, copy number 11: AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P.
- chr8:41,490,396–133,963,259, 1,359 genes, copy number 9–11 (broad region; genes not listed).
- chr8:134,477,788–139,127,953, 36 genes, copy number 11: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr11:54,591,480–57,427,580, 149 genes, copy number 10 (broad region; genes not listed).
- chr20:11,234,170–11,345,855, 2 genes, copy number 10: AL049649.1, RPS11P1.
- chr20:16,576,068–18,271,069, 42 genes, copy number 11: AL049794.1, AL049794.2, RPLP0P1, Y_RNA, AL135938.1, AL034428.1, SNRPB2, OTOR, AL121892.1, U3, RNU6-27P, AL359511.1, RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1, RRBP1, BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2.
- chr20:18,295,143–18,295,451, 1 gene, copy number 11: RN7SKP74.
- chr20:28,563,850–64,313,132, 918 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
